Somatic mutation profile of tumor specimen TARGET-10-PAPEJL-09A (aliquot TARGET-10-PAPEJL-09A-01D) from TARGET case TARGET-10-PAPEJL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.5 years (3,475 days).
Specimen TARGET-10-PAPEJL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c290b454-d3b3-4c54-8074-ee4e030fe9a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEJL-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEJL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3db1100d-2d9b-48a3-aa46-7954b056aee1

The open-access MAF lists 119 somatic variants for this specimen: 77 protein-altering or splice-affecting, 16 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 16, Intron 12, 3'UTR 5, RNA 5, Nonsense Mutation 4, 3'Flank 2, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs730880472, COSV55534139; ClinVar: likely pathogenic; called by muse, varscan2
- PDHA1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794149, CM000556, CM981496, COSV58832138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM32 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs199865553; called by muse, mutect2, varscan2
- ADGRL3 | c.2474C>T p.T825M (on ENST00000506720 / NM_001322402.2; = p.T757M on NM_015236.6) | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746668174, COSV72229218; called by muse, mutect2, varscan2
- ANO3 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as rs777889841, COSV56783616; called by muse, mutect2, varscan2
- ATP1A4 | c.1607C>G p.S536* | Nonsense Mutation (SNP) | VAF 35/96 reads (36%) | catalogued as COSV63626874; called by muse, mutect2, varscan2
- ATP5MC2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100101000; called by muse, mutect2, varscan2
- ATRX | c.3440A>G p.K1147R | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as rs1461556034; called by muse, mutect2, varscan2
- BBS10 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99674300; called by muse, mutect2, varscan2
- C11orf58 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.217); catalogued as rs1411616921; called by muse, mutect2, varscan2
- CALN1 | c.56G>A p.R19Q (on ENST00000329008 / NM_001017440.3; = p.R61Q on NM_031468.4) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.921); catalogued as COSV61123306, COSV61145362; called by muse, mutect2, varscan2
- CEP295NL | c.1724C>G p.S575W | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs553520865; called by muse, mutect2, varscan2
- DCUN1D5 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52784012; called by muse, mutect2, varscan2
- EPS8L3 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763054655; called by muse, mutect2, varscan2
- GLB1L2 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs201933932; called by muse, mutect2, varscan2
- HMBS | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs756417575, COSV53830091; called by muse, mutect2, varscan2
- ITPR2 | c.5581G>C p.E1861Q | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV67268647; called by muse, mutect2, varscan2
- KCTD16 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV72577987; called by muse, mutect2, varscan2
- MEGF8 | c.5738C>T p.S1913F (on ENST00000251268 / NM_001271938.2; = p.S1846F on NM_001410.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as COSV52075474; called by muse, mutect2, varscan2
- MYO1E | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs1566988453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE4B | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772252118; called by muse, mutect2, varscan2
- POF1B | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as COSV53140827; called by muse, mutect2, varscan2
- PSD2 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs201061729; called by muse, mutect2, varscan2
- PXDN | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as rs768133091, COSV53243394; called by muse, mutect2, varscan2
- SEMA3C | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs780071714; called by muse, mutect2, varscan2
- SLC39A2 | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.134); catalogued as rs1484129477; called by muse, mutect2, varscan2
- SNAP91 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs547981536, COSV99534771; called by muse, mutect2, varscan2
- SPHKAP | c.4966G>C p.D1656H (on ENST00000392056 / NM_001142644.2; = p.D1627H on NM_030623.3) | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60885521; called by muse, mutect2, varscan2
- SUPT7L | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV58134165; called by muse, mutect2, varscan2
- TTN | c.9048G>A p.M3016I (on ENST00000591111; = p.M2970I on NM_003319.4) | Missense Mutation (SNP) | VAF 57/110 reads (52%) | PolyPhen benign (0); catalogued as COSV100627535; called by muse, mutect2, varscan2
- VIL1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754807183, COSV50285429; called by muse, mutect2, varscan2
- ZNF25 | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.629); catalogued as rs748230784; called by muse, mutect2, varscan2
- ZNF572 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs1421825418; called by muse, mutect2, varscan2
- ZNF582 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as rs377725485; called by muse, mutect2, varscan2
- ZNF732 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs376831555; called by muse, mutect2, varscan2
- ANOS1 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAZ1B | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CCDC6 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CCNA1 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CEP295NL | c.1456C>G p.Q486E | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CFTR | c.3804G>C p.Q1268H | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CLIP3 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLVS2 | c.480G>C p.L160F | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- COPZ1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP24A1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DARS2 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FHOD1 | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GJA1 | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IFITM3 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- IMP3 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MACF1 | c.11143G>A p.E3715K (on ENST00000372915; = p.E1648K on NM_012090.5) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- MATN2 | c.2175G>A p.M725I | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- MDH1B | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2
- MDN1 | c.10702G>T p.E3568* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- MYEF2 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- NAA35 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- NGEF | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM33 | c.1999C>G p.Q667E | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- RGS3 | c.973G>C p.D325H (on ENST00000350696 / NM_001282923.2; = p.D213H on NM_017790.4) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIPPLY3 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- RPL23A | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL23A | c.209+3C>A | Splice Region (SNP) | VAF 42/115 reads (37%) | called by muse, varscan2
- SAE1 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUPT7L | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TNRC6A | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TPP2 | c.2795G>A p.G932E | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- U2SURP | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USH2A | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- VRK3 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF184 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF287 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF33B | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); called by muse, mutect2
- ZNF77 | c.947G>T p.R316M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ZNF77 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ZNF90 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF90 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZPR1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMCX4 | c.474G>A p.Q158= (on ENST00000433011; = p.Q54= on NM_001256155.2) | Silent (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- BOD1L1 | c.9147G>A p.A3049= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs747400099, COSV99239559; called by muse, mutect2, varscan2
- CDH18 | c.1833G>A p.L611= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1381407091; called by muse, mutect2, varscan2
- CDH2 | c.2419C>A p.R807= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV52277750, COSV99297309; called by muse, mutect2
- CPS1 | c.1461C>A p.I487= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- CRYBG3 | c.3960G>A p.L1320= | Silent (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- MAEA | c.132C>T p.T44= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as rs1279747500; called by muse, mutect2
- MS4A3 | c.534G>C p.L178= | Silent (SNP) | VAF 50/120 reads (42%) | called by muse, mutect2
- MYH4 | c.1305C>T p.Y435= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs201920700, COSV55116378; called by muse, mutect2, varscan2
- PABPC3 | c.630C>G p.L210= | Silent (SNP) | VAF 71/222 reads (32%) | catalogued as rs1279662656; called by muse, mutect2, varscan2
- PER2 | c.2217G>A p.Q739= | Silent (SNP) | VAF 54/100 reads (54%) | called by muse, mutect2, varscan2
- PRDM13 | c.885C>T p.F295= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- SPATA25 | c.408G>A p.P136= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs138752668; called by muse, mutect2
- TRO | c.375C>A p.T125= | Silent (SNP) | VAF 42/93 reads (45%) | called by muse, mutect2, varscan2
- ZBTB21 | c.1329C>T p.I443= | Silent (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- ZPR1 | c.447G>A p.L149= | Silent (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- ABCA6 | c.3012+1190C>G | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- ADD3-AS1 | n.6133C>G | RNA (SNP) | VAF 65/141 reads (46%) | called by muse, mutect2, varscan2
- AKT1S1 | c.*91C>G | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2
- ARHGAP5 | c.-73G>A | 5'UTR (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100565668; called by muse, mutect2, varscan2
- ATG2B | chr14:96275935 G>A | 3'Flank (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- ATG2B | chr14:96276296 G>C | 3'Flank (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- BRWD3 | c.813+48G>A | Intron (SNP) | VAF 24/52 reads (46%) | catalogued as rs1215987741; called by muse, mutect2, varscan2
- CENPJ | c.3302-637C>T | Intron (SNP) | VAF 29/63 reads (46%) | catalogued as rs561170522; called by muse, mutect2, varscan2
- COQ6 | c.299-66G>A | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- COQ6 | c.299-65G>A | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- COQ6 | c.358-22G>A | Intron (SNP) | VAF 11/34 reads (32%) | called by muse, varscan2
- DST | c.16635+277G>C | Intron (SNP) | VAF 59/124 reads (48%) | called by muse, mutect2, varscan2
- EMC6 | c.*37C>T | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- FAM166C | c.462-276G>C | Intron (SNP) | VAF 14/28 reads (50%) | catalogued as COSV56600456; called by muse, varscan2
- IL36B | c.261+1113C>T | Intron (SNP) | VAF 17/35 reads (49%) | catalogued as rs75083712; called by muse, mutect2, varscan2
- LINC01619 | n.1381G>C | RNA (SNP) | VAF 58/68 reads (85%) | called by muse, mutect2, varscan2
- MICU3 | c.694+163G>C | Intron (SNP) | VAF 10/23 reads (43%) | catalogued as rs1451421834; called by muse, mutect2
- MIR202 | n.6C>T | RNA (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- PIPSL | n.2563G>C | RNA (SNP) | VAF 57/160 reads (36%) | called by muse, mutect2, varscan2
- PYY3 | n.93C>G | RNA (SNP) | VAF 28/59 reads (47%) | catalogued as rs1348447550; called by muse, mutect2, varscan2
- RPL23A | c.209+86C>G | Intron (SNP) | VAF 29/74 reads (39%) | called by muse, varscan2
- SGK1 | c.787-107C>T | Intron (SNP) | VAF 26/56 reads (46%) | catalogued as rs1459069907; called by muse, mutect2, varscan2
- SP110 | c.*121G>C | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- TMEM14C | c.*101G>A | 3'UTR (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- U2AF1L4 | c.*184C>T | 3'UTR (SNP) | VAF 55/112 reads (49%) | catalogued as rs778476545, COSV53075628; called by muse, mutect2, varscan2
- UBN1 | chr16:4847120 C>T | 5'Flank (SNP) | VAF 7/12 reads (58%) | catalogued as rs938144070; called by muse, mutect2, varscan2
